FM case AD13008 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/31c744af-2a89-4887-82e6-14ab92668d93

Female, 54.6 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
